Somatic mutation profile of tumor specimen TCGA-FU-A5XV-01A (aliquot TCGA-FU-A5XV-01A-11D-A28B-09) from TCGA case TCGA-FU-A5XV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 32.0 years (11,692 days).
Specimen TCGA-FU-A5XV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74f3345d-c8fb-44f0-9e59-8853dd821cd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A5XV-10A (Blood Derived Normal), aliquot TCGA-FU-A5XV-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/034a143f-1592-40a4-b56e-f90c8021ccea

The open-access MAF lists 100 somatic variants for this specimen: 74 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 24, Nonsense Mutation 6, Splice Site 3, Splice Region 3, Frame Shift Ins 2, Frame Shift Del 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 35/68 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACD | c.1006G>A p.E336K (on ENST00000620338; = p.E247K on NM_022914.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV54667344; called by muse, mutect2, varscan2
- APOBEC4 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV58017545; called by muse, mutect2, varscan2
- AS3MT | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54916727; called by muse, mutect2, varscan2
- BUB1B | c.2007G>C p.L669= | Splice Region (SNP) | VAF 41/114 reads (36%) | catalogued as COSV55012220; called by muse, mutect2, varscan2
- C9 | c.1125del p.D376Tfs*2 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | catalogued as rs1195276908; called by mutect2, pindel, varscan2
- CAMK2B | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51659940; called by muse, mutect2, varscan2
- CAMKK2 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV61214407; called by muse, mutect2, varscan2
- CAPN12 | c.429C>G p.L143= | Splice Region (SNP) | VAF 30/53 reads (57%) | catalogued as COSV61015892; called by muse, mutect2, varscan2
- CD163L1 | c.3644C>T p.T1215M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs774379913, COSV58015111, COSV58026644; called by muse, mutect2, varscan2
- CFAP65 | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs772580613, COSV100446018, COSV58560424; called by muse, mutect2, varscan2
- CNIH3 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as COSV55275310, COSV99686016; called by muse, mutect2, varscan2
- CNTLN | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52076167; called by muse, mutect2, varscan2
- CRAMP1 | c.3675G>T p.M1225I | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50188750; called by muse, mutect2, varscan2
- CYB5R1 | c.746-1G>C p.X249_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as COSV61851396; called by muse, mutect2, varscan2
- DDIT4L | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as COSV56767288; called by muse, mutect2, varscan2
- DDX27 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.677); catalogued as COSV100873315; called by muse, varscan2
- DNAH3 | c.1176C>A p.H392Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV54518562; called by muse, mutect2, varscan2
- E2F7 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as rs780614837, COSV59739397; called by muse, mutect2, varscan2
- ENTPD4 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs372875344; called by muse, mutect2, varscan2
- ERBB4 | c.3899C>T p.P1300L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61483208; called by muse, mutect2, varscan2
- EXOC3 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs376575084; called by muse, mutect2, varscan2
- GALNT17 | c.116T>G p.F39C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.339); catalogued as COSV61159934; called by muse, mutect2, varscan2
- GAP43 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59343895; called by muse, mutect2
- GNAI3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV63983679; called by muse, mutect2, varscan2
- H4C5 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63486069; called by muse, mutect2, varscan2
- HTR2B | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51449628; called by muse, mutect2, varscan2
- ICE1 | c.3427G>C p.V1143L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs752804823, COSV56823413; called by muse, mutect2, varscan2
- IRX4 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs753385487, COSV51472219; called by muse, mutect2, varscan2
- KCNH7 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59794983, COSV59797598; called by muse, mutect2, varscan2
- KIF1B | c.2675G>T p.S892I (on ENST00000377086 / NM_001365952.1; = p.S846I on NM_015074.3) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV55807996; called by muse, mutect2, varscan2
- LIPH | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1342838431, COSV56183782; called by muse, mutect2, varscan2
- MAP3K21 | c.2899C>T p.Q967* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs761367644, COSV64041578; called by muse, mutect2, varscan2
- MAP4K5 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50154031; called by muse, mutect2, varscan2
- MEP1A | c.753G>C p.E251D | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.601); catalogued as COSV57919659; called by muse, mutect2, varscan2
- MYH15 | c.2881G>C p.E961Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV56308956; called by muse, mutect2, varscan2
- NBPF1 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.55); catalogued as COSV99844353; called by muse, mutect2, varscan2
- NCF2 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62315335; called by muse, mutect2, varscan2
- NHLH2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866172895, COSV100204939; called by muse, mutect2, varscan2
- NMT2 | c.1371G>C p.L457F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65382099; called by muse, mutect2, varscan2
- NUP98 | c.2356C>G p.L786V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs556807510, COSV61431541; called by muse, mutect2, varscan2
- OR6C1 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV104428280, COSV65573324; called by muse, mutect2, varscan2
- PDGFRB | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55804181; called by muse, mutect2, varscan2
- PLCE1 | c.4891G>C p.D1631H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53348436, COSV53358128; called by muse, mutect2, varscan2
- POU6F2 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV68872794; called by muse, mutect2, varscan2
- PRDM16 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs1408714731, COSV54588024; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF4 | c.203C>T p.S68F (on ENST00000374198 / NM_001322267.2; = p.S69F on NM_004697.5) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV65252578; called by muse, mutect2, varscan2
- PTPDC1 | c.265A>G p.N89D (on ENST00000375360 / NM_177995.3; = p.N141D on NM_152422.4) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1180575656, COSV56622896; called by muse, mutect2, varscan2
- REPS1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs752858400, COSV57810281; called by muse, mutect2, varscan2
- RHD | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs200307239, CM973730, COSV59646009; called by muse, mutect2, varscan2
- RNASE11 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100250447, COSV60087524; called by muse, mutect2, varscan2
- RNF208 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1219530147, COSV61287560; called by muse, mutect2, varscan2
- SBNO1 | c.3955G>A p.E1319K (on ENST00000420886; = p.E1318K on NM_018183.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV57341156; called by muse, mutect2, varscan2
- SEZ6L | c.1683G>A p.A561= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as rs199961565, COSV50662660, COSV50676296; called by muse, mutect2, varscan2
- SLC26A8 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs189677862; called by muse, mutect2, varscan2
- SLC5A11 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs991826030, COSV61741329; called by muse, mutect2, varscan2
- SLITRK1 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1210891744, COSV65674557; called by muse, mutect2
- SNAP91 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV52121194; called by muse, mutect2, varscan2
- SPTAN1 | c.5938C>T p.Q1980* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV63985291, COSV63987027; called by muse, mutect2
- SQSTM1 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52972939, COSV99481687; called by muse, mutect2, varscan2
- SUPT20H | c.1398C>G p.I466M (on ENST00000350612 / NM_001014286.3; = p.I467M on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV100634625; called by muse, mutect2, varscan2
- SUSD1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV62583411; called by muse, mutect2, varscan2
- TADA1 | c.233-2A>T p.X78_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV63310202; called by muse, mutect2
- TENT5A | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60787970; called by muse, mutect2, varscan2
- TRIM50 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 54/153 reads (35%) | catalogued as COSV60792857; called by muse, mutect2, varscan2
- U2SURP | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV67530696; called by muse, mutect2, varscan2
- ZFC3H1 | c.1837C>G p.P613A | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66432091; called by muse, mutect2, varscan2
- ZNF101 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs558462983, COSV58908860; called by muse, mutect2, varscan2
- ZWINT | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as COSV59185240; called by muse, mutect2, varscan2
- CEBPZ | c.3153dup p.Q1052Tfs*7 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- DDX52 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GABRA3 | c.278_282del p.V93Dfs*2 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by pindel, varscan2
- KMT2A | c.11271dup p.N3759Efs*9 | Frame Shift Ins (INS) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- RAB31 | c.274-27_282del p.X92_splice | Splice Site (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel
- ABCA8 | c.1857G>A p.L619= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV99285348; called by muse, mutect2, varscan2
- ALAS2 | c.1338G>A p.L446= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as rs757784147, COSV58189987; called by muse, mutect2, varscan2
- ATAD5 | c.2352C>T p.S784= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV58976054; called by muse, mutect2
- C2CD3 | c.852G>C p.L284= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV58092743; called by muse, mutect2, varscan2
- CGB1 | c.282G>T p.V94= | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as COSV56819775; called by muse, mutect2, varscan2
- CYP2C19 | c.942G>A p.L314= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV64907611; called by muse, mutect2, varscan2
- DEFB113 | c.237C>A p.L79= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV59037785; called by muse, mutect2, varscan2
- DNAH3 | c.8877C>T p.I2959= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs770455378, COSV54518319, COSV54518543; called by muse, mutect2, varscan2
- DTX4 | c.1032G>A p.L344= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV57090235; called by muse, mutect2, varscan2
- EPHB4 | c.2850C>T p.I950= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as rs1173336501, COSV62268698; called by muse, mutect2, varscan2
- JMY | c.2424T>G p.P808= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV68660746; called by muse, mutect2, varscan2
- NPIPA1 | c.858C>G p.L286= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV60154207; called by muse, mutect2, varscan2
- ORC6 | c.15G>C p.L5= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV54478376; called by muse, mutect2, varscan2
- PDZK1 | c.15C>T p.F5= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV61092193; called by muse, mutect2, varscan2
- PHYKPL | c.75C>A p.L25= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV57424030; called by muse, mutect2, varscan2
- PLPP3 | c.237T>C p.T79= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV64839302; called by muse, mutect2, varscan2
- PLPP6 | c.666G>C p.S222= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV56305089; called by muse, mutect2, varscan2
- PUDP | c.144G>C p.L48= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV66903769; called by muse, mutect2, varscan2
- RIMBP3 | c.3801G>A p.P1267= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs1469067860; called by mutect2, varscan2
- SHKBP1 | c.192C>T p.F64= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV52537706; called by muse, mutect2, varscan2
- SLC17A6 | c.318C>T p.R106= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as rs1289420055, COSV54134443, COSV54142618; called by muse, mutect2, varscan2
- SV2A | c.1920C>T p.F640= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV64964623; called by muse, mutect2, varscan2
- UGT1A10 | c.174C>T p.V58= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs1453192033, COSV60837507; called by muse, mutect2, varscan2
- ZNF446 | c.621G>A p.R207= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV52180546; called by muse, mutect2, varscan2
- FRMPD2B | n.1279G>A | RNA (SNP) | VAF 41/149 reads (28%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.914+126G>C | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as COSV59235053; called by muse, mutect2, varscan2
